Somatic mutation profile of tumor specimen C3L-02358-03 (aliquot CPT0112720006) from CPTAC case C3L-02358, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 75.8 years (27,672 days).
Specimen C3L-02358-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df7925f2-ac03-4c66-a58e-8bdbecef7e26.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02358-31 (Blood Derived Normal), aliquot CPT0115190002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5396b10b-b94e-4ed6-8de4-ef01ce02e9c2

The open-access MAF lists 279 somatic variants for this specimen: 185 protein-altering or splice-affecting, 61 silent, 33 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 166, Silent 61, Intron 13, 5'UTR 7, Nonsense Mutation 7, Frame Shift Del 7, 3'UTR 4, RNA 4, 3'Flank 3, Splice Site 2, 5'Flank 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.313G>C p.G105R | Missense Mutation (SNP) | VAF 93/140 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1060501195, CM043949, COSV52726068, COSV52741717, COSV53015551; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AGMO | c.718C>A p.L240I | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs772538285; called by muse, mutect2, varscan2
- AOC1 | c.2182C>T p.R728C | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.698); catalogued as rs768381765, COSV62866910, COSV62867798; called by muse, mutect2, varscan2
- CD1C | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777045453, COSV63806397; called by muse, mutect2, varscan2
- COL3A1 | c.2956A>T p.N986Y | Missense Mutation (SNP) | VAF 59/247 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100482840; called by muse, mutect2, varscan2
- CSAD | c.530G>T p.R177L (on ENST00000444623 / NM_001244705.2; = p.R204L on NM_015989.5) | Missense Mutation (SNP) | VAF 231/629 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.078); catalogued as COSV57244725; called by muse, mutect2, varscan2
- DYSF | c.5377G>T p.A1793S | Missense Mutation (SNP) | VAF 152/456 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1299043154; called by muse, mutect2, varscan2
- FAM135B | c.2672C>A p.P891H | Missense Mutation (SNP) | VAF 158/286 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.436); catalogued as COSV52725228; called by muse, mutect2, varscan2
- FOXB1 | c.410T>C p.L137P | Missense Mutation (SNP) | VAF 80/619 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as rs1442423243; called by muse, mutect2, varscan2
- FRMPD3 | c.5026C>A p.R1676S | Missense Mutation (SNP) | VAF 71/228 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV99346326; called by muse, mutect2, varscan2
- FUT9 | c.505G>T p.G169C | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100132850; called by muse, mutect2, varscan2
- GAGE10 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 133/265 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs782053450, COSV68163709; called by muse, mutect2, varscan2
- GLG1 | c.1493G>A p.R498H | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs752607666, COSV52664177; called by muse, mutect2, varscan2
- GRM8 | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as rs937573816; called by muse, mutect2, varscan2
- HERC2 | c.511G>T p.G171C | Missense Mutation (SNP) | VAF 59/150 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.281); catalogued as COSV55346571; called by muse, mutect2, varscan2
- HNRNPH2 | c.279G>T p.M93I | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.319); catalogued as COSV54508588; called by muse, mutect2, varscan2
- IGHV6-1 | c.239A>G p.Y80C | Missense Mutation (SNP) | VAF 32/350 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs782172744; called by muse, mutect2
- IRS4 | c.3766G>C p.G1256R | Missense Mutation (SNP) | VAF 59/214 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100929542; called by muse, mutect2, varscan2
- ITPR3 | c.4000G>A p.V1334M | Missense Mutation (SNP) | VAF 44/258 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.936); catalogued as rs370348085; called by muse, mutect2, varscan2
- JCAD | c.3589G>C p.E1197Q | Missense Mutation (SNP) | VAF 82/269 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.608); catalogued as rs753150800; called by muse, mutect2, varscan2
- KATNIP | c.2974G>A p.G992S | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776639555; called by muse, mutect2, varscan2
- KMT2C | c.10495C>G p.Q3499E | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.05); catalogued as rs745749081, COSV51514513; called by muse, mutect2, varscan2
- LILRB4 | c.1035G>A p.M345I (on ENST00000391733 / NM_001278428.3; = p.M344I on NM_001278426.3) | Missense Mutation (SNP) | VAF 121/218 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs746620223; called by muse, mutect2, varscan2
- LPAR4 | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70913446; called by muse, mutect2, varscan2
- LRP2 | c.3265C>T p.R1089C | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.601); catalogued as rs763860226, COSV55542058; called by muse, mutect2, varscan2
- LRTM2 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.179); catalogued as COSV54564353; called by muse, mutect2, varscan2
- MAGI2 | c.344G>C p.R115P | Missense Mutation (SNP) | VAF 72/214 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV62641607; called by muse, mutect2, varscan2
- MED12 | c.5138G>T p.R1713L | Missense Mutation (SNP) | VAF 61/207 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV99048841; called by muse, mutect2, varscan2
- MED12 | c.6454G>C p.A2152P | Missense Mutation (SNP) | VAF 221/698 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV61349294; called by muse, mutect2, varscan2
- MED12L | c.3527T>C p.V1176A | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs751776926; called by muse, mutect2, varscan2
- MGAM | c.3134A>G p.H1045R | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs376565637; called by muse, mutect2, varscan2
- MMRN1 | c.3146C>T p.P1049L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1236756752, COSV53334893; called by muse, mutect2, varscan2
- MNDA | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.321); catalogued as rs1329858284; called by muse, mutect2, varscan2
- MYOCD | c.544G>T p.A182S | Missense Mutation (SNP) | VAF 92/164 reads (56%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as COSV58506565; called by muse, mutect2, varscan2
- NAV3 | c.4312G>A p.E1438K | Missense Mutation (SNP) | VAF 81/156 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.492); catalogued as COSV99890850; called by muse, mutect2, varscan2
- NF1 | c.8059_8060del p.S2687Cfs*5 (on ENST00000358273 / NM_001042492.3; = p.S2666Cfs*5 on NM_000267.3) | Frame Shift Del (DEL) | VAF 74/192 reads (39%) | catalogued as rs1060500387; called by pindel, varscan2
- NPHP4 | c.1006G>C p.A336P | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs369951224; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NR3C2 | c.877C>G p.L293V | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs757712786; called by muse, mutect2, varscan2
- OGDH | c.2126A>G p.N709S | Missense Mutation (SNP) | VAF 47/244 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs778217546, COSV56046663; called by muse, mutect2, varscan2
- OPRPN | c.622C>G p.L208V | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.028); catalogued as rs771601540, COSV104434734; called by muse, mutect2, varscan2
- OR1J1 | c.928G>C p.A310P | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV52237174; called by muse, mutect2
- OR2T1 | c.382C>A p.P128T | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV63542762; called by muse, mutect2, varscan2
- OR5D14 | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as rs376987168, COSV59456133; called by muse, mutect2, varscan2
- OR5L1 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 79/244 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.517); catalogued as COSV61734773; called by muse, mutect2, varscan2
- OR6K3 | c.258G>T p.E86D (on ENST00000368146; = p.E70D on NM_001005327.2) | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1427638497, COSV63746602; called by muse, mutect2, varscan2
- P2RX3 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 71/393 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs767341122; called by muse, mutect2, varscan2
- PCDH15 | c.5083G>T p.E1695* | Nonsense Mutation (SNP) | VAF 24/58 reads (41%) | catalogued as COSV57315355; called by muse, mutect2, varscan2
- PCDHB14 | c.1613C>T p.S538F | Missense Mutation (SNP) | VAF 301/656 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.548); catalogued as rs782538892; called by muse, mutect2, varscan2
- PCDHGB4 | c.1734C>A p.H578Q | Missense Mutation (SNP) | VAF 234/527 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV53955612; called by muse, mutect2, varscan2
- PDE1C | c.9C>A p.D3E | Missense Mutation (SNP) | VAF 90/432 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs764631278; called by muse, mutect2
- SCN10A | c.3440G>T p.R1147L | Missense Mutation (SNP) | VAF 54/228 reads (24%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.737); catalogued as COSV101479488; called by muse, mutect2, varscan2
- SCN11A | c.2794G>C p.D932H | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.689); catalogued as COSV56570261; called by mutect2, varscan2
- SEPTIN11 | c.820C>T p.R274* | Nonsense Mutation (SNP) | VAF 43/152 reads (28%) | catalogued as COSV53583128; called by muse, mutect2, varscan2
- SF3B1 | c.2356A>G p.K786E | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59211125; called by muse, mutect2, varscan2
- SGCE | c.394G>T p.D132Y (on ENST00000647096; = p.D96Y on NM_003919.3) | Missense Mutation (SNP) | VAF 68/182 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM133100; called by muse, mutect2, varscan2
- SIGLEC12 | c.1654G>A p.A552T (on ENST00000291707 / NM_053003.4; = p.A434T on NM_033329.2) | Missense Mutation (SNP) | VAF 40/67 reads (60%) | SIFT tolerated (0.24); PolyPhen benign (0.04); catalogued as rs1456926344, COSV99389514; called by mutect2, varscan2
- SLC35F1 | c.1186G>T p.G396C | Missense Mutation (SNP) | VAF 118/305 reads (39%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.909); catalogued as rs755608722; called by muse, mutect2, varscan2
- SYT10 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 61/341 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57345350; called by muse, mutect2, varscan2
- TAF9B | c.205G>C p.D69H | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs781899334; called by muse, mutect2, varscan2
- TRH | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.154); catalogued as rs1238235089, COSV57015494; called by muse, mutect2
- UBR4 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV64397521; called by muse, mutect2, varscan2
- USH2A | c.3679G>T p.G1227C | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56334174; called by muse, mutect2, varscan2
- USP13 | c.1636C>T p.Q546* | Nonsense Mutation (SNP) | VAF 77/311 reads (25%) | catalogued as COSV55863192; called by muse, mutect2, varscan2
- VWC2 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 75/208 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV61483836, COSV61485442; called by muse, mutect2, varscan2
- XIRP2 | c.3553G>A p.D1185N (on ENST00000628543; = p.D1360N on NM_152381.6) | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV54681969; called by muse, mutect2, varscan2
- ZFAT | c.3013A>G p.I1005V | Missense Mutation (SNP) | VAF 190/760 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.622); catalogued as rs371911015; called by muse, mutect2, varscan2
- ZNF785 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs763963998, COSV67876625; called by muse, mutect2, varscan2
- ABCA13 | c.12442_12448del p.D4148Pfs*2 | Frame Shift Del (DEL) | VAF 27/66 reads (41%) | called by mutect2, pindel, varscan2
- ADAM8 | c.927G>T p.M309I | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- ADAMTS14 | c.2519A>G p.N840S | Missense Mutation (SNP) | VAF 53/185 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- ADGRL4 | c.396+2T>C p.X132_splice | Splice Site (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2, varscan2
- AK7 | c.1956A>G p.I652M | Missense Mutation (SNP) | VAF 87/280 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ALG13 | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 68/202 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- AMOT | c.735G>T p.K245N | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, varscan2
- ANKLE1 | c.1280T>G p.L427R (on ENST00000394458; = p.L373R on NM_152363.6) | Missense Mutation (SNP) | VAF 105/307 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- ANKRD35 | c.2327C>G p.S776C | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AP5B1 | c.2374G>A p.E792K | Missense Mutation (SNP) | VAF 120/457 reads (26%) | SIFT tolerated (0.95); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARMCX6 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 72/218 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ATG2A | c.3203G>T p.R1068L | Missense Mutation (SNP) | VAF 104/270 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- B4GAT1 | c.1226C>A p.P409H | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- BSN | c.7954T>C p.S2652P | Missense Mutation (SNP) | VAF 47/240 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- C11orf42 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 231/406 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- CBFA2T3 | c.1838C>A p.A613D | Missense Mutation (SNP) | VAF 86/247 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC59 | c.224A>G p.K75R | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CFAP54 | c.1585C>T p.L529F | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CLEC1A | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CLEC1B | c.426C>A p.N142K | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- CNTLN | c.2596del p.E866Rfs*3 | Frame Shift Del (DEL) | VAF 14/26 reads (54%) | called by mutect2, pindel, varscan2
- COPA | c.1574A>G p.H525R | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- CPSF1 | c.2575_2592+6del p.X859_splice | Splice Site (DEL) | VAF 297/532 reads (56%) | called by mutect2, pindel*, varscan2*
- CSMD3 | c.3346G>T p.D1116Y (on ENST00000297405 / NM_001363185.1; = p.D1012Y on NM_052900.3) | Missense Mutation (SNP) | VAF 80/342 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CSRP3 | c.35C>A p.A12D | Missense Mutation (SNP) | VAF 244/734 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CTU2 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CYLD | c.1616G>T p.C539F | Missense Mutation (SNP) | VAF 91/244 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYP8B1 | c.1440G>T p.W480C | Missense Mutation (SNP) | VAF 63/223 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- DEF8 | c.218A>T p.Q73L (on ENST00000268676 / NM_207514.3; = p.Q12L on NM_017702.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/279 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- DIS3L | c.206A>T p.Y69F | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- DLG2 | c.2060G>C p.G687A | Missense Mutation (SNP) | VAF 83/168 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- DSTYK | c.184A>G p.T62A | Missense Mutation (SNP) | VAF 123/338 reads (36%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- ECEL1 | c.1000G>T p.D334Y | Missense Mutation (SNP) | VAF 89/350 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EFS | c.965C>A p.P322H | Missense Mutation (SNP) | VAF 35/51 reads (69%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EIF2S3B | c.1302C>A p.C434* | Nonsense Mutation (SNP) | VAF 119/351 reads (34%) | called by muse, mutect2, varscan2
- ETV6 | c.1210C>G p.L404V | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FANCB | c.451T>C p.F151L | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- FUS | c.785T>A p.F262Y | Missense Mutation (SNP) | VAF 56/329 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- GABRB1 | c.518A>T p.Q173L | Missense Mutation (SNP) | VAF 83/255 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GIPC3 | c.890C>T p.P297L (on ENST00000644946; = p.P293S on NM_133261.3) | Missense Mutation (SNP) | VAF 300/467 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- GPR174 | c.937C>G p.Q313E | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HNRNPH2 | c.280G>T p.D94Y | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HS3ST4 | c.226C>A p.P76T | Missense Mutation (SNP) | VAF 75/190 reads (39%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- HSF4 | c.1178G>A p.G393E (on ENST00000521374 / NM_001040667.3; = p.G363E on NM_001538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 90/584 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, varscan2
- IGF2R | c.1649A>T p.K550I | Missense Mutation (SNP) | VAF 47/190 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- IGHM | c.62C>A p.T21K | Missense Mutation (SNP) | VAF 104/339 reads (31%) | SIFT tolerated (0.55); called by muse, mutect2, varscan2
- IGKV2D-26 | c.340A>C p.M114L | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2
- INTS6L | c.2224G>C p.A742P | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- IQCJ | c.476A>T p.Q159L | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCNN1 | c.1249C>T p.Q417* | Nonsense Mutation (SNP) | VAF 136/356 reads (38%) | called by muse, mutect2, varscan2
- KLHL13 | c.1742G>T p.G581V | Missense Mutation (SNP) | VAF 57/235 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LCT | c.2392G>T p.A798S | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- LONRF2 | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MKRN3 | c.1042A>G p.R348G | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTARC1 | c.34T>A p.F12I | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MUC16 | c.30602C>A p.T10201N | Missense Mutation (SNP) | VAF 83/141 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- MYO9B | c.2573A>C p.E858A | Missense Mutation (SNP) | VAF 136/310 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- NEXMIF | c.1925del p.P642Hfs*30 | Frame Shift Del (DEL) | VAF 38/105 reads (36%) | called by mutect2, pindel, varscan2
- NF2 | c.20C>A p.S7Y | Missense Mutation (SNP) | VAF 151/377 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- NKX6-3 | c.434C>A p.T145N | Missense Mutation (SNP) | VAF 104/362 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- NPY5R | c.62C>A p.A21D | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NR1I2 | c.563T>C p.L188P | Missense Mutation (SNP) | VAF 129/441 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NRK | c.3769G>A p.E1257K | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR10Q1 | c.420G>A p.M140I | Missense Mutation (SNP) | VAF 105/276 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- OR10Q1 | c.269dup p.L90Ffs*36 | Frame Shift Ins (INS) | VAF 61/294 reads (21%) | called by mutect2, pindel, varscan2
- OR2J2 | c.808G>T p.D270Y | Missense Mutation (SNP) | VAF 73/212 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- P4HB | c.865A>T p.I289F | Missense Mutation (SNP) | VAF 150/359 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- PARP10 | c.2704T>A p.F902I | Missense Mutation (SNP) | VAF 68/1142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCM1 | c.1401T>A p.Y467* | Nonsense Mutation (SNP) | VAF 27/174 reads (16%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.4021T>C p.S1341P | Missense Mutation (SNP) | VAF 80/313 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLCG2 | c.1156G>T p.V386L | Missense Mutation (SNP) | VAF 66/200 reads (33%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- POU4F2 | c.478C>G p.P160A | Missense Mutation (SNP) | VAF 74/246 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- PRAMEF19 | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 88/264 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- PRAMEF20 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 47/352 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- PTGER2 | c.524A>G p.Y175C | Missense Mutation (SNP) | VAF 156/241 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- RAD51AP2 | c.1225A>T p.N409Y | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- RMND5B | c.737del p.G246Afs*53 | Frame Shift Del (DEL) | VAF 57/154 reads (37%) | called by mutect2, pindel, varscan2
- RNF152 | c.93G>T p.K31N | Missense Mutation (SNP) | VAF 351/483 reads (73%) | SIFT tolerated (0.19); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- ROCK2 | c.2555G>T p.R852L | Missense Mutation (SNP) | VAF 57/284 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- RPL15 | c.193C>A p.R65S | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- RPS24 | c.350T>C p.V117A | Missense Mutation (SNP) | VAF 84/200 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.018); called by muse, varscan2
- RTL9 | c.762G>T p.E254D | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SH3D21 | c.224G>T p.R75L | Missense Mutation (SNP) | VAF 129/257 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SHANK3 | c.3757G>T p.G1253C | Missense Mutation (SNP) | VAF 193/461 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- SLC41A2 | c.580A>T p.T194S | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- SLC7A1 | c.1072A>T p.M358L | Missense Mutation (SNP) | VAF 79/125 reads (63%) | SIFT tolerated (0.22); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- SLITRK4 | c.586A>G p.I196V | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SMARCD1 | c.415G>T p.E139* | Nonsense Mutation (SNP) | VAF 47/157 reads (30%) | called by muse, mutect2, varscan2
- STARD9 | c.6156G>C p.R2052S | Missense Mutation (SNP) | VAF 78/268 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- TBC1D2 | c.593A>C p.Q198P | Missense Mutation (SNP) | VAF 191/327 reads (58%) | SIFT tolerated (0.28); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- TBX22 | c.409C>A p.Q137K | Missense Mutation (SNP) | VAF 123/393 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TEX11 | c.1837G>A p.A613T (on ENST00000344304; = p.A598T on NM_031276.3) | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- TPCN2 | c.730G>T p.D244Y | Missense Mutation (SNP) | VAF 67/227 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TRIM50 | c.984G>T p.Q328H | Missense Mutation (SNP) | VAF 185/664 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRRAP | c.8666G>T p.G2889V (on ENST00000359863 / NM_001244580.1; = p.G2871V on NM_003496.3) | Missense Mutation (SNP) | VAF 201/1181 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- UBE2E2 | c.421G>T p.D141Y | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UBQLN3 | c.76G>T p.V26L | Missense Mutation (SNP) | VAF 95/171 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- UCHL5 | c.140A>T p.K47M | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- UGT3A1 | c.1180C>A p.Q394K | Missense Mutation (SNP) | VAF 93/519 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC45A | c.1508G>T p.C503F | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VAMP1 | c.344_346del p.Y115del | In Frame Del (DEL) | VAF 6/26 reads (23%) | called by mutect2, pindel, varscan2
- VEZF1 | c.636G>C p.K212N | Missense Mutation (SNP) | VAF 79/133 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- VGLL2 | c.670C>A p.P224T | Missense Mutation (SNP) | VAF 257/487 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- VPS51 | c.1659+8A>T | Splice Region (SNP) | VAF 78/193 reads (40%) | called by muse, mutect2, varscan2
- VRTN | c.1829A>T p.Q610L | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WDR17 | c.3593C>T p.S1198L | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WEE2 | c.89T>A p.V30E | Missense Mutation (SNP) | VAF 79/202 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZDHHC14 | c.830G>A p.S277N | Missense Mutation (SNP) | VAF 57/270 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- ZFHX4 | c.707G>T p.R236I | Missense Mutation (SNP) | VAF 127/211 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- ZFHX4 | c.7508C>T p.P2503L | Missense Mutation (SNP) | VAF 155/539 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ZFP62 | c.353G>C p.R118P (on ENST00000502412 / NM_001377944.1; = p.R85P on NM_152283.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/141 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF107 | c.1625A>C p.H542P | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZNF516 | c.2238del p.N746Kfs*12 | Frame Shift Del (DEL) | VAF 109/515 reads (21%) | called by mutect2, pindel, varscan2
- ZNF536 | c.334G>T p.G112C | Missense Mutation (SNP) | VAF 350/608 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF618 | c.349_355del p.P117Afs*22 | Frame Shift Del (DEL) | VAF 123/251 reads (49%) | called by mutect2, pindel, varscan2
- ZNF711 | c.705A>T p.K235N | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- ZNF716 | c.298G>C p.E100Q | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ZSCAN25 | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- ADGRA1 | c.1281T>C p.P427= | Silent (SNP) | VAF 68/243 reads (28%) | catalogued as rs777948743; called by muse, mutect2, varscan2
- ARRDC2 | c.660C>T p.A220= | Silent (SNP) | VAF 366/882 reads (41%) | catalogued as rs773728534; called by muse, mutect2, varscan2
- ASXL3 | c.900A>G p.L300= | Silent (SNP) | VAF 74/114 reads (65%) | catalogued as COSV52480425; called by muse, varscan2
- C8B | c.384A>G p.A128= | Silent (SNP) | VAF 61/369 reads (17%) | called by muse, mutect2, varscan2
- CD27 | c.714G>A p.R238= | Silent (SNP) | VAF 69/241 reads (29%) | catalogued as rs770816422; called by muse, mutect2, varscan2
- CDH9 | c.564C>T p.D188= | Silent (SNP) | VAF 18/189 reads (10%) | catalogued as rs766465003, COSV50257070, COSV99148019; called by muse, mutect2
- CFAP61 | c.3576G>T p.P1192= | Silent (SNP) | VAF 172/498 reads (35%) | called by muse, mutect2, varscan2
- COL3A1 | c.2034T>C p.G678= | Silent (SNP) | VAF 121/421 reads (29%) | called by muse, mutect2, varscan2
- CRYBB1 | c.217C>A p.R73= | Silent (SNP) | VAF 204/528 reads (39%) | called by muse, mutect2, varscan2
- DCAF12L1 | c.1149G>T p.L383= | Silent (SNP) | VAF 48/188 reads (26%) | called by muse, mutect2, varscan2
- DDX28 | c.1230G>T p.V410= | Silent (SNP) | VAF 19/111 reads (17%) | called by muse, mutect2, varscan2
- DIAPH1 | c.735C>T p.V245= | Silent (SNP) | VAF 13/211 reads (6%) | catalogued as rs771150697, COSV99526902; called by muse, mutect2
- DNAJC5B | c.198C>T p.N66= | Silent (SNP) | VAF 216/900 reads (24%) | catalogued as rs748413301, COSV99396043; called by muse, mutect2, varscan2
- DTHD1 | c.1353T>A p.G451= (on ENST00000456874; = p.G286= on NM_001136536.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/147 reads (21%) | called by muse, mutect2, varscan2
- EFTUD2 | c.1332C>T p.G444= | Silent (SNP) | VAF 94/197 reads (48%) | catalogued as rs765631040, COSV101274551; called by muse, mutect2, varscan2
- FAM47C | c.234C>A p.L78= | Silent (SNP) | VAF 67/134 reads (50%) | called by muse, mutect2, varscan2
- FRMD7 | c.1428G>T p.T476= | Silent (SNP) | VAF 57/239 reads (24%) | catalogued as COSV100049178; called by muse, mutect2, varscan2
- FZD10 | c.1356C>G p.T452= | Silent (SNP) | VAF 77/269 reads (29%) | called by muse, mutect2, varscan2
- GGNBP2 | c.507G>A p.T169= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as rs751525603; called by muse, mutect2, varscan2
- GHRHR | c.381C>A p.S127= | Silent (SNP) | VAF 135/543 reads (25%) | called by muse, mutect2, varscan2
- GPR55 | c.198G>A p.L66= | Silent (SNP) | VAF 87/326 reads (27%) | called by muse, mutect2, varscan2
- H2AC16 | c.114C>T p.G38= | Silent (SNP) | VAF 182/475 reads (38%) | catalogued as rs780435458; called by muse, mutect2, varscan2
- HHIPL1 | c.1437C>T p.Y479= | Silent (SNP) | VAF 40/389 reads (10%) | catalogued as rs759187122, COSV58090484; called by muse, mutect2, varscan2
- IL16 | c.2463T>C p.A821= (on ENST00000302987 / NM_172217.5; = p.A120= on NM_004513.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 43/146 reads (29%) | called by muse, mutect2, varscan2
- IL1RAPL2 | c.201C>A p.A67= | Silent (SNP) | VAF 78/282 reads (28%) | called by muse, mutect2, varscan2
- KANK4 | c.2865C>T p.D955= | Silent (SNP) | VAF 190/535 reads (36%) | called by muse, mutect2, varscan2
- KBTBD13 | c.177C>T p.R59= | Silent (SNP) | VAF 84/274 reads (31%) | catalogued as rs772474725; called by muse, varscan2
- KCNH8 | c.3234A>G p.A1078= | Silent (SNP) | VAF 57/167 reads (34%) | called by muse, mutect2, varscan2
- LAP3 | c.690C>T p.T230= | Silent (SNP) | VAF 32/106 reads (30%) | catalogued as rs756389161; called by muse, mutect2, varscan2
- LAS1L | c.504C>T p.D168= | Silent (SNP) | VAF 33/142 reads (23%) | called by muse, mutect2, varscan2
- LMNA | c.918C>T p.L306= | Silent (SNP) | VAF 240/707 reads (34%) | catalogued as COSV61542011; called by muse, mutect2, varscan2
- MAGEA11 | c.546C>A p.P182= | Silent (SNP) | VAF 78/236 reads (33%) | called by muse, mutect2, varscan2
- MERTK | c.2220G>T p.A740= | Silent (SNP) | VAF 113/321 reads (35%) | catalogued as COSV54925568; called by muse, mutect2, varscan2
- MRPS18C | c.159A>G p.S53= | Silent (SNP) | VAF 40/139 reads (29%) | called by muse, mutect2, varscan2
- OR2M2 | c.204C>A p.L68= | Silent (SNP) | VAF 40/126 reads (32%) | catalogued as COSV62898713; called by muse, mutect2, varscan2
- PCDH15 | c.1857G>T p.L619= | Silent (SNP) | VAF 114/360 reads (32%) | called by muse, mutect2, varscan2
- PIEZO1 | c.2034C>T p.S678= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs918800272; called by muse, mutect2, varscan2
- PIK3CA | c.1182T>C p.P394= | Silent (SNP) | VAF 70/180 reads (39%) | called by muse, mutect2, varscan2
- PLXND1 | c.4785G>A p.V1595= | Silent (SNP) | VAF 22/111 reads (20%) | called by muse, mutect2, varscan2
- PTPN22 | c.462C>G p.G154= | Silent (SNP) | VAF 73/164 reads (45%) | called by muse, mutect2, varscan2
- QRICH2 | c.3969C>T p.A1323= | Silent (SNP) | VAF 25/214 reads (12%) | catalogued as rs373111630; called by muse, mutect2, varscan2
- RBM46 | c.402G>A p.V134= | Silent (SNP) | VAF 29/102 reads (28%) | called by muse, mutect2, varscan2
- SNCB | c.133C>A p.R45= | Silent (SNP) | VAF 168/364 reads (46%) | catalogued as rs771426940; called by muse, mutect2, varscan2
- SOX3 | c.591C>A p.A197= | Silent (SNP) | VAF 244/762 reads (32%) | called by muse, mutect2, varscan2
- STAG2 | c.2991G>A p.L997= | Silent (SNP) | VAF 14/121 reads (12%) | catalogued as COSV54356551; called by muse, mutect2, varscan2
- TAF1 | c.204C>A p.T68= | Silent (SNP) | VAF 45/177 reads (25%) | catalogued as COSV99335407; called by muse, mutect2, varscan2
- TARBP1 | c.3852T>C p.F1284= | Silent (SNP) | VAF 25/116 reads (22%) | called by muse, mutect2, varscan2
- TCL1A | c.117C>A p.I39= | Silent (SNP) | VAF 113/213 reads (53%) | catalogued as COSV68085271; called by muse, mutect2, varscan2
- TLR8 | c.618A>G p.L206= (on ENST00000218032 / NM_138636.5; = p.L224= on NM_016610.4) | Silent (SNP) | VAF 21/50 reads (42%) | called by muse, mutect2, varscan2
- TOR1AIP2 | c.411G>T p.V137= | Silent (SNP) | VAF 25/180 reads (14%) | called by muse, mutect2, varscan2
- TRMT1L | c.27G>C p.L9= | Silent (SNP) | VAF 63/174 reads (36%) | called by muse, mutect2, varscan2
- TRPC5 | c.1146C>A p.L382= | Silent (SNP) | VAF 60/244 reads (25%) | called by muse, mutect2, varscan2
- TTN | c.87291G>T p.L29097= (on ENST00000591111; = p.L21673= on NM_003319.4) | Silent (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- TXNL4B | c.402T>C p.I134= | Silent (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- TYW1 | c.639C>T p.G213= | Silent (SNP) | VAF 42/285 reads (15%) | catalogued as rs751029423; called by muse, mutect2, varscan2
- UNC79 | c.4470G>A p.P1490= (on ENST00000393151 / NM_001346218.2; = p.P1313= on NM_020818.5) | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs762137118, COSV56393695; called by muse, mutect2
- USH1C | c.966G>T p.R322= | Silent (SNP) | VAF 255/454 reads (56%) | called by muse, mutect2, varscan2
- YIPF7 | c.576G>C p.L192= | Silent (SNP) | VAF 73/261 reads (28%) | called by muse, mutect2, varscan2
- ZFP14 | c.258C>T p.T86= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99524997; called by muse, mutect2, varscan2
- ZFR2 | c.813C>T p.H271= | Silent (SNP) | VAF 117/190 reads (62%) | called by muse, mutect2, varscan2
- ZNF142 | c.3510C>G p.S1170= (on ENST00000411696 / NM_001379660.1; = p.S970= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- ADAM22 | c.86-17C>T | Intron (SNP) | VAF 65/289 reads (22%) | called by muse, mutect2, varscan2
- AGAP14P | n.1862G>T | RNA (SNP) | VAF 225/998 reads (23%) | catalogued as rs1387695043; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73821189 A>G | 3'Flank (SNP) | VAF 74/175 reads (42%) | called by muse, mutect2, varscan2
- BCLAF3 | c.1951-708G>A | Intron (SNP) | VAF 4/56 reads (7%) | catalogued as rs1046996454; called by muse, mutect2
- CHTF8 | c.141+104A>G | Intron (SNP) | VAF 42/216 reads (19%) | called by muse, mutect2, varscan2
- CYLC1 | c.-6G>T | 5'UTR (SNP) | VAF 28/140 reads (20%) | catalogued as COSV100254168; called by muse, mutect2, varscan2
- DIO3 | chr14:101557564 C>A | 5'Flank (SNP) | VAF 60/119 reads (50%) | called by muse, mutect2, varscan2
- ENPEP | c.1510-930C>A | Intron (SNP) | VAF 37/158 reads (23%) | called by muse, mutect2, varscan2
- FGF23 | c.212-21C>A | Intron (SNP) | VAF 122/384 reads (32%) | called by muse, mutect2, varscan2
- G6PD | chrX:154531974 C>A | 3'Flank (SNP) | VAF 77/252 reads (31%) | called by muse, mutect2, varscan2
- GABRA3 | c.-26-29859C>A | Intron (SNP) | VAF 73/273 reads (27%) | called by muse, mutect2, varscan2
- H2BP2 | n.1062-259G>C | Intron (SNP) | VAF 131/415 reads (32%) | called by muse, mutect2, varscan2
- HERC2 | c.13273-125G>T | Intron (SNP) | VAF 246/581 reads (42%) | called by muse, mutect2, varscan2
- IGBP1 | c.-44_-43insC | 5'UTR (INS) | VAF 57/202 reads (28%) | called by mutect2, pindel, varscan2
- IGHG1 | chr14:105740141 C>A | 3'Flank (SNP) | VAF 40/485 reads (8%) | called by muse, mutect2, varscan2
- LEKR1 | c.*338G>T | 3'UTR (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- NEB | c.18826-1324G>A | Intron (SNP) | VAF 109/365 reads (30%) | called by muse, mutect2, varscan2
- NKX3-2 | c.*9G>A | 3'UTR (SNP) | VAF 91/284 reads (32%) | called by muse, mutect2, varscan2
- OR1F2P | n.721G>T | RNA (SNP) | VAF 37/113 reads (33%) | called by muse, mutect2, varscan2
- OR2W5 | n.1024C>T | RNA (SNP) | VAF 81/278 reads (29%) | called by muse, mutect2, varscan2
- PDE8B | c.-22C>A | 5'UTR (SNP) | VAF 50/94 reads (53%) | called by muse, mutect2, varscan2
- RBBP4 | c.-55C>T | 5'UTR (SNP) | VAF 43/209 reads (21%) | catalogued as rs1452598988; called by muse, mutect2, varscan2
- SORCS1 | c.3371+241C>T | Intron (SNP) | VAF 22/193 reads (11%) | catalogued as rs904792464; called by muse, mutect2, varscan2
- SYT14 | c.*36G>T | 3'UTR (SNP) | VAF 95/290 reads (33%) | called by muse, mutect2, varscan2
- TAZ | c.*566C>T | 3'UTR (SNP) | VAF 197/698 reads (28%) | called by muse, mutect2, varscan2
- TCEAL4 | c.-68C>T | 5'UTR (SNP) | VAF 25/136 reads (18%) | called by muse, mutect2, varscan2
- TMEM11 | c.62+3087A>C | Intron (SNP) | VAF 137/222 reads (62%) | called by muse, mutect2, varscan2
- TPRXL | n.1150C>T | RNA (SNP) | VAF 91/342 reads (27%) | called by muse, varscan2
- TTC39A | c.-16A>C | 5'UTR (SNP) | VAF 30/198 reads (15%) | called by muse, mutect2, varscan2
- TTC39A | c.-17G>T | 5'UTR (SNP) | VAF 30/194 reads (15%) | called by muse, mutect2, varscan2
- TWF1 | c.25+639C>A | Intron (SNP) | VAF 35/89 reads (39%) | called by muse, mutect2, varscan2
- ZNF160 | c.15+25G>T | Intron (SNP) | VAF 18/22 reads (82%) | catalogued as rs369553618; called by muse, mutect2, varscan2
- ZNF467 | chr7:149777312 T>C | 5'Flank (SNP) | VAF 236/381 reads (62%) | called by muse, mutect2, varscan2
